Somatic mutation profile of tumor specimen TCGA-EK-A2RL-01A (aliquot TCGA-EK-A2RL-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 33.0 years (12,047 days).
Specimen TCGA-EK-A2RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cca12fad-1402-4652-a389-ca35c97acf00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RL-10A (Blood Derived Normal), aliquot TCGA-EK-A2RL-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3851ebe-942c-45ec-8a6b-c224b012c0de

The open-access MAF lists 32 somatic variants for this specimen: 16 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 14, 3'UTR 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>T p.R465L (on ENST00000281708 / NM_001349798.2; = p.R385L on NM_018315.5) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/49 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASCC2 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs146488197; called by muse, mutect2, varscan2
- ATRX | c.6800C>A p.T2267N | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); catalogued as COSV64874576; called by muse, mutect2, varscan2
- COL2A1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs765231668, COSV61529593, COSV61534007; called by muse, mutect2, varscan2
- CYP4F12 | c.1168A>T p.R390W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV61173284; called by muse, mutect2, varscan2
- EPHA6 | c.2909C>A p.P970H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101065325; called by muse, mutect2, varscan2
- NSD2 | c.3995C>T p.S1332L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs561070783, COSV56389229; called by muse, mutect2, varscan2
- SH3GLB1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs777019424, COSV65279582; called by muse, mutect2, varscan2
- TOM1 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as rs371088274; called by muse, mutect2, varscan2
- TRHDE | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs762647325, COSV53832847; called by muse, mutect2, varscan2
- TRRAP | c.3819G>T p.K1273N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV62842466; called by muse, mutect2, varscan2
- XPO1 | c.2532T>G p.H844Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV68945503; called by muse, mutect2, varscan2
- ZNF264 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs912212830, COSV54041398, COSV99567088; called by muse, mutect2, varscan2
- ACVR2A | c.762dup p.R255Tfs*6 | Frame Shift Ins (INS) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- GPD1L | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.157); called by muse, mutect2
- AHI1 | c.2667C>A p.P889= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99663636; called by muse, mutect2
- ANKK1 | c.2283C>T p.A761= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as rs1464150930, COSV58271232; called by muse, mutect2, varscan2
- C10orf82 | c.31C>T p.L11= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as COSV65021781; called by muse, mutect2, varscan2
- CDK6 | c.564C>T p.P188= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs748277804, COSV56006788; called by muse, mutect2, varscan2
- CFAP44 | c.1278C>T p.F426= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV55610476; called by muse, mutect2, varscan2
- CHRM5 | c.1371G>A p.P457= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs140200556; called by muse, mutect2, varscan2
- CPAMD8 | c.270G>C p.A90= (on ENST00000651564; = p.A43= on NM_015692.5) | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV52233176; called by muse, mutect2, varscan2
- GNPAT | c.969C>T p.S323= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as COSV64153266; called by muse, mutect2, varscan2
- MT1H | c.45C>T p.C15= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs765420008, COSV60090800; called by muse, mutect2, varscan2
- NFASC | c.2082G>A p.P694= (on ENST00000339876 / NM_001378329.1; = p.P690= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs764323507, COSV58368828; called by muse, mutect2, varscan2
- PRKD1 | c.2220G>T p.R740= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV59564362; called by muse, mutect2, varscan2
- SYNGR2 | c.558G>A p.P186= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs142613283; called by muse, mutect2, varscan2
- UNC5D | c.2322G>A p.P774= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs772701180, COSV54784385; called by muse, mutect2, varscan2
- VRTN | c.1437G>A p.A479= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs754149597, COSV56439346; called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79623G>A | Intron (SNP) | VAF 27/58 reads (47%) | catalogued as COSV58145670; called by muse, mutect2, varscan2
- OTOF | c.*163C>G | 3'UTR (SNP) | VAF 19/98 reads (19%) | catalogued as COSV55500634; called by muse, mutect2, varscan2
